Somatic mutation profile of tumor specimen TCGA-68-8250-01A (aliquot TCGA-68-8250-01A-11D-2293-08) from TCGA case TCGA-68-8250, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 66.0 years (24,118 days).
Specimen TCGA-68-8250-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b9beb32b-35f6-401a-8282-b81460082773.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-68-8250-10A (Blood Derived Normal), aliquot TCGA-68-8250-10A-01D-2293-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a201337-3e6d-440a-9592-a44641a8065f

The open-access MAF lists 322 somatic variants for this specimen: 259 protein-altering or splice-affecting, 57 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 223, Silent 57, Nonsense Mutation 18, Frame Shift Del 8, Splice Site 7, 3'Flank 3, Splice Region 2, Intron 1, RNA 1, Nonstop Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.310C>T p.Q104* | Nonsense Mutation (SNP) | VAF 52/89 reads (58%) | hotspot (GDC flag); catalogued as rs1567555934, COSV52694629; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.2581G>A p.G861R (on ENST00000404938 / NM_001163941.2; = p.G416R on NM_178559.6) | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99329033; called by muse, mutect2, varscan2
- ALMS1 | c.10121C>G p.S3374* | Nonsense Mutation (SNP) | VAF 38/194 reads (20%) | catalogued as CM156246; called by muse, mutect2, varscan2
- APRT | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs117335001, COSV51936831; called by muse, mutect2, varscan2
- ARHGAP30 | c.2477C>G p.A826G | Missense Mutation (SNP) | VAF 17/198 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as COSV63518773; called by muse, mutect2
- ASAH1 | c.16G>C p.G6R | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.007); catalogued as rs1414926619; called by muse, mutect2, varscan2
- ASB3 | c.109G>T p.D37Y | Missense Mutation (SNP) | VAF 96/510 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750767404, COSV54857933; called by muse, mutect2, varscan2
- ATP1A2 | c.2813G>A p.R938H | Missense Mutation (SNP) | VAF 68/317 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs759097524, COSV100767806, COSV100768062; called by muse, mutect2
- C11orf58 | c.529T>G p.F177V | Missense Mutation (SNP) | VAF 67/280 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1050082410, COSV99930336; called by muse, mutect2, varscan2
- CACNA1A | c.1819C>T p.L607F | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV64210590; called by muse, mutect2, varscan2
- CASP8AP2 | c.1985G>T p.R662M | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.264); catalogued as rs1362608530, COSV99387240; called by muse, mutect2
- CD36 | c.17A>G p.N6S | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as rs750185259; called by muse, mutect2, varscan2
- CENPJ | c.1557G>C p.K519N | Missense Mutation (SNP) | VAF 74/153 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV101121585; called by muse, mutect2, varscan2
- CEP41 | c.973+2T>G p.X325_splice | Splice Site (SNP) | VAF 57/178 reads (32%) | catalogued as COSV99782795; called by muse, mutect2, varscan2
- CKAP5 | c.76A>G p.S26G | Missense Mutation (SNP) | VAF 70/265 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as rs777290124; called by muse, mutect2, varscan2
- CLEC9A | c.112G>T p.V38L | Missense Mutation (SNP) | VAF 75/173 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV100872759; called by muse, mutect2, varscan2
- COL2A1 | c.242C>G p.P81R | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.354); catalogued as COSV61532361; called by muse, mutect2, varscan2
- CSMD3 | c.6427C>G p.L2143V (on ENST00000297405 / NM_001363185.1; = p.L2039V on NM_052900.3) | Missense Mutation (SNP) | VAF 81/329 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.649); catalogued as COSV99827672; called by muse, mutect2, varscan2
- DIP2B | c.3810+2T>G p.X1270_splice | Splice Site (SNP) | VAF 30/116 reads (26%) | catalogued as COSV99998866; called by muse, mutect2, varscan2
- DLGAP3 | c.715G>T p.G239C | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs377200647; called by muse, mutect2, varscan2
- DNAJB13 | c.392G>T p.R131L | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.178); catalogued as rs770415081, COSV100334508, COSV60271303; called by muse, mutect2, varscan2
- DSG4 | c.819+1G>T p.X273_splice | Splice Site (SNP) | VAF 17/114 reads (15%) | catalogued as COSV100356114; called by muse, mutect2, varscan2
- FAM217A | c.1430T>C p.I477T | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs766010596; called by muse, mutect2, varscan2
- FSCB | c.178A>G p.T60A | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.09); catalogued as rs773887213; called by muse, mutect2, varscan2
- GABRB1 | c.1091A>G p.H364R | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.265); catalogued as rs1560380725; called by muse, mutect2, varscan2
- GRIA2 | c.1766C>T p.T589I | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.782); catalogued as COSV99645244; called by muse, mutect2, varscan2
- GULP1 | c.390C>A p.S130R | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63065554; called by muse, mutect2, varscan2
- H2BW1 | c.133C>A p.Q45K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.968); catalogued as COSV99475089; called by muse, mutect2, varscan2
- HFM1 | c.3140C>A p.T1047K | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.147); catalogued as COSV54029040; called by muse, mutect2, varscan2
- HK3 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0.033); catalogued as rs766901550, COSV52837044; called by muse, mutect2, varscan2
- HS3ST4 | c.705G>T p.R235S | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV58833196; called by muse, mutect2, varscan2
- HTR2A | c.295G>C p.V99L | Missense Mutation (SNP) | VAF 9/153 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101096755; called by muse, mutect2
- IFI16 | c.754A>G p.K252E | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs372267762; called by muse, mutect2, varscan2
- KCNA6 | c.159G>C p.E53D | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV54975318; called by muse, mutect2, varscan2
- KIAA1841 | c.1760C>G p.P587R | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.368); catalogued as rs1465854557; called by muse, mutect2, varscan2
- KIF26A | c.4408T>C p.S1470P | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs933433052; called by muse, mutect2, varscan2
- KIR3DL3 | c.968A>C p.H323P | Missense Mutation (SNP) | VAF 12/221 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.194); catalogued as COSV99400035; called by muse, mutect2
- L1CAM | c.1243G>C p.A415P | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as CM023949; called by muse, mutect2, varscan2
- LCE2B | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 38/309 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.046); catalogued as rs759790443; called by muse, mutect2, varscan2
- LRGUK | c.670+1G>T p.X224_splice | Splice Site (SNP) | VAF 18/84 reads (21%) | catalogued as COSV99604444; called by muse, mutect2, varscan2
- LRRTM4 | c.391C>A p.P131T | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.079); catalogued as COSV69142855; called by muse, mutect2, varscan2
- MAGEB6B | c.867G>A p.M289I | Missense Mutation (SNP) | VAF 89/140 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.278); catalogued as rs1569250343; called by muse, mutect2, varscan2
- MARCHF6 | c.1896+1G>A p.X632_splice | Splice Site (SNP) | VAF 23/92 reads (25%) | catalogued as COSV99929953; called by muse, mutect2, varscan2
- MARK1 | c.1730G>T p.R577L | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV65065893, COSV65067743; called by muse, mutect2, varscan2
- MED14 | c.713G>A p.G238E | Missense Mutation (SNP) | VAF 41/69 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as rs773227786, COSV61358312; called by muse, mutect2, varscan2
- MPLKIP | c.28A>G p.T10A | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as rs1341459656; called by muse, mutect2, varscan2
- MTNR1A | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs764154841, COSV56155268; called by muse, mutect2, varscan2
- MUC16 | c.11142T>G p.H3714Q | Missense Mutation (SNP) | VAF 11/175 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.079); catalogued as COSV101200399; called by muse, mutect2
- OLAH | c.677G>C p.G226A (on ENST00000378228 / NM_001039702.3; = p.G279A on NM_018324.3) | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs139895854; called by muse, mutect2, varscan2
- OR14I1 | c.56G>T p.W19L | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV61199546; called by muse, mutect2, varscan2
- OR14K1 | c.634A>G p.I212V | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.531); catalogued as rs752772652; called by muse, mutect2, varscan2
- OR2G3 | c.316G>C p.A106P | Missense Mutation (SNP) | VAF 74/280 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.804); catalogued as COSV60681660; called by muse, mutect2, varscan2
- OR52E8 | c.551A>T p.Y184F | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV66206608; called by muse, mutect2, varscan2
- OSBPL7 | c.412C>G p.R138G | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.469); catalogued as rs772141294, COSV50108549; called by muse, mutect2, varscan2
- PAX3 | c.658C>A p.R220S | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60586705; called by muse, mutect2, varscan2
- PCDHA11 | c.1609C>T p.R537C | Missense Mutation (SNP) | VAF 87/201 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.12); catalogued as COSV56479043, COSV56490464; called by muse, mutect2, varscan2
- PDE11A | c.920G>T p.R307L | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs779465413, COSV53711784; called by muse, mutect2, varscan2
- PGLS | c.590G>C p.R197P | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV53115524; called by muse, mutect2, varscan2
- PHF3 | c.2074G>T p.D692Y | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100013921; called by muse, mutect2, varscan2
- PKD1 | c.843C>G p.H281Q | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as COSV99238465; called by muse, varscan2
- PODXL | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.737); catalogued as rs150410872; called by muse, varscan2
- PPP1R3F | c.1676G>T p.R559L | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.273); catalogued as COSV50017759; called by muse, mutect2, varscan2
- PTPMT1 | c.364C>T p.Q122* | Nonsense Mutation (SNP) | VAF 16/107 reads (15%) | catalogued as COSV100442971; called by muse, mutect2, varscan2
- RHBG | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as rs949879394; called by muse, mutect2, varscan2
- RIMS1 | c.4960G>C p.G1654R | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53465230; called by muse, mutect2, varscan2
- RIT2 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 88/267 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV99951274; called by muse, mutect2, varscan2
- RP1 | c.424G>A p.V142I | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.022); catalogued as rs367600337, COSV55109473, COSV55128616; called by muse, mutect2, varscan2
- RSPO2 | c.257G>T p.R86L | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52640795; called by muse, mutect2, varscan2
- RYR2 | c.12529G>T p.V4177F | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100770415, COSV63663437; called by muse, mutect2, varscan2
- SLC12A5 | c.1837C>G p.R613G (on ENST00000454036 / NM_001134771.2; = p.R590G on NM_020708.5) | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.75); catalogued as COSV54804588; called by muse, mutect2
- SLC22A16 | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as rs767217245, COSV57927896, COSV57928998; called by muse, mutect2, varscan2
- SLC5A9 | c.1587C>A p.H529Q | Missense Mutation (SNP) | VAF 97/272 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52582362; called by muse, mutect2, varscan2
- SNCAIP | c.142A>T p.S48C | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs763264876; called by muse, mutect2, varscan2
- SULF1 | c.1384C>T p.Q462* | Nonsense Mutation (SNP) | VAF 25/135 reads (19%) | catalogued as COSV52683175; called by muse, mutect2, varscan2
- TAF1L | c.4192A>G p.T1398A | Missense Mutation (SNP) | VAF 34/488 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs542280744; called by muse, mutect2
- TAS2R20 | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 17/319 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as rs376156307; called by muse, mutect2
- TG | c.3278G>C p.R1093T | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99602388; called by muse, mutect2, varscan2
- TMEM132D | c.654G>C p.Q218H | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV70602328; called by muse, mutect2, varscan2
- TMEM69 | c.245G>A p.R82K | Missense Mutation (SNP) | VAF 44/384 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1286790252; called by muse, mutect2, varscan2
- TRIM55 | c.1577G>A p.G526D | Missense Mutation (SNP) | VAF 72/362 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.037); catalogued as COSV52542738; called by muse, mutect2, varscan2
- TTN | c.67069C>T p.R22357C (on ENST00000591111; = p.R14933C on NM_003319.4) | Missense Mutation (SNP) | VAF 23/143 reads (16%) | PolyPhen probably damaging (0.998); catalogued as COSV59906477; called by muse, mutect2, varscan2
- TYW1 | c.953G>A p.G318D | Missense Mutation (SNP) | VAF 8/197 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100658876; called by muse, mutect2
- UROC1 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1191312116; called by muse, mutect2, varscan2
- XIRP2 | c.378G>T p.Q126H (on ENST00000628543; = p.Q301H on NM_152381.6) | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as COSV99738822; called by muse, mutect2, varscan2
- ZFYVE9 | c.3942G>C p.V1314= | Splice Region (SNP) | VAF 24/105 reads (23%) | catalogued as rs907213526; called by muse, mutect2, varscan2
- ZNF331 | c.775A>G p.I259V | Missense Mutation (SNP) | VAF 64/163 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99466855; called by muse, mutect2, varscan2
- ZNF354C | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV100203687; called by muse, mutect2
- ZNF611 | c.63+1G>T p.X21_splice | Splice Site (SNP) | VAF 94/593 reads (16%) | catalogued as COSV100160437; called by muse, mutect2, varscan2
- ABL2 | c.1394A>C p.K465T (on ENST00000502732 / NM_007314.4; = p.K450T on NM_005158.5) | Missense Mutation (SNP) | VAF 86/226 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRV1 | c.8714A>T p.N2905I | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- ANKRD26 | c.4386A>T p.R1462S | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ANO4 | c.2288G>T p.R763M (on ENST00000392977 / NM_001286615.2; = p.R728M on NM_178826.4) | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- ANTXR2 | c.584A>C p.Q195P | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- AP3B1 | c.1024T>A p.L342I | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- ARHGAP31 | c.3332C>A p.P1111H | Missense Mutation (SNP) | VAF 60/225 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ARHGAP32 | c.757G>T p.E253* | Nonsense Mutation (SNP) | VAF 35/121 reads (29%) | called by muse, mutect2, varscan2
- ASB13 | c.513T>G p.N171K | Missense Mutation (SNP) | VAF 85/191 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AXDND1 | c.1046A>G p.K349R | Missense Mutation (SNP) | VAF 50/384 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- BABAM2 | c.134C>G p.T45R | Missense Mutation (SNP) | VAF 7/159 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.66); called by muse, mutect2
- BCL11A | c.1351G>T p.E451* (on ENST00000335712 / NM_001365609.1; = p.E485* on NM_018014.4) | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- BMP7 | c.449G>T p.R150L | Missense Mutation (SNP) | VAF 32/373 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2
- BRD8 | c.2812G>A p.A938T | Missense Mutation (SNP) | VAF 114/259 reads (44%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRPF3 | c.3212G>T p.R1071L | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- BZW2 | c.854G>A p.R285K | Missense Mutation (SNP) | VAF 44/201 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- C12orf40 | c.1675G>A p.V559M | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CCDC39 | c.1734G>C p.K578N | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CEP63 | c.2091A>T p.R697S | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- CEP78 | c.554G>C p.G185A | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CEP97 | c.2246G>T p.G749V | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- CFAP58 | c.210G>T p.E70D | Missense Mutation (SNP) | VAF 51/90 reads (57%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- CHD5 | c.5548A>G p.N1850D | Missense Mutation (SNP) | VAF 58/286 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- CNTLN | c.835G>T p.D279Y | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- COL11A1 | c.4399C>A p.Q1467K | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- COL24A1 | c.1301G>T p.R434I | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- CPS1 | c.2391G>T p.E797D | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- CSMD3 | c.9143G>T p.C3048F (on ENST00000297405 / NM_001363185.1; = p.C2879F on NM_052900.3) | Missense Mutation (SNP) | VAF 65/316 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD3 | c.2752T>C p.S918P (on ENST00000297405 / NM_001363185.1; = p.S814P on NM_052900.3) | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTDNEP1 | c.271C>G p.P91A | Missense Mutation (SNP) | VAF 27/214 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- DBX1 | c.908C>G p.P303R | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2
- DCK | c.76A>G p.I26V | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- DDHD2 | c.449A>G p.K150R | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- DGKI | c.2896G>T p.A966S | Missense Mutation (SNP) | VAF 70/171 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- DHH | c.519G>T p.W173C | Missense Mutation (SNP) | VAF 110/386 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DIAPH2 | c.3099G>C p.K1033N | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- DMD | c.10981G>T p.E3661* | Nonsense Mutation (SNP) | VAF 41/66 reads (62%) | called by muse, mutect2, varscan2
- DMD | c.5264C>T p.P1755L | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- DNAH11 | c.6680G>C p.G2227A | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DNAJC13 | c.6205G>T p.A2069S | Missense Mutation (SNP) | VAF 33/203 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNHD1 | c.554T>A p.L185Q | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- DPF3 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DST | c.2799G>C p.M933I (on ENST00000361203 / NM_001374722.1; = p.M607I on NM_001723.6) | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- DTNB | c.1855A>T p.K619* | Nonsense Mutation (SNP) | VAF 96/336 reads (29%) | called by muse, mutect2, varscan2
- DZANK1 | c.344A>T p.N115I | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.127); called by muse, mutect2
- EIF1AD | c.455A>G p.Y152C | Missense Mutation (SNP) | VAF 58/271 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERICH3 | c.826A>T p.R276* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2, varscan2
- ETNK1 | c.885del p.T296Lfs*8 | Frame Shift Del (DEL) | VAF 45/187 reads (24%) | called by mutect2, pindel, varscan2
- FAM135B | c.990A>T p.Q330H | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM78B | c.521T>C p.V174A | Missense Mutation (SNP) | VAF 106/272 reads (39%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- FAM81A | c.668A>T p.E223V | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FAT3 | c.13085G>A p.G4362E | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- FBN3 | c.7151G>A p.G2384D | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- FGFR3 | c.134A>G p.Q45R | Missense Mutation (SNP) | VAF 30/213 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FGFR4 | c.785T>G p.V262G | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); called by muse, mutect2
- FIP1L1 | c.795G>T p.K265N | Missense Mutation (SNP) | VAF 100/180 reads (56%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FPR2 | c.1037C>A p.T346N | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- FSD2 | c.419C>G p.A140G | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- FZD6 | c.31A>G p.I11V | Missense Mutation (SNP) | VAF 48/89 reads (54%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FZD9 | c.292C>A p.P98T | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GAB1 | c.339C>A p.D113E | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- GABRA6 | c.530-1G>T p.X177_splice | Splice Site (SNP) | VAF 13/34 reads (38%) | called by muse, mutect2, varscan2
- GLB1L2 | c.449G>T p.S150I | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- GLIS1 | c.937C>T p.Q313* | Nonsense Mutation (SNP) | VAF 24/107 reads (22%) | called by muse, mutect2, varscan2
- GON4L | c.277G>T p.E93* | Nonsense Mutation (SNP) | VAF 79/191 reads (41%) | called by muse, mutect2, varscan2
- GPR78 | c.955C>A p.P319T | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- GRM8 | c.492C>G p.N164K | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- HMCN1 | c.2758C>G p.P920A | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- HMCN1 | c.3833G>T p.R1278I | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HOXB2 | c.293T>A p.M98K | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HOXB3 | c.232C>G p.L78V | Missense Mutation (SNP) | VAF 37/63 reads (59%) | SIFT tolerated (0.19); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- IGLV3-22 | c.113G>T p.R38M | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- IGSF22 | c.76C>G p.Q26E | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IRGC | c.1232C>A p.P411Q | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- ITCH | c.2135T>A p.L712Q (on ENST00000262650 / NM_001257137.3; = p.L671Q on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/219 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KCNH5 | c.767T>A p.V256D | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KHK | c.701G>A p.G234D | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KIAA1549 | c.5030A>T p.Q1677L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- KIF1A | c.1135C>A p.L379M | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF2B | c.424A>T p.M142L | Missense Mutation (SNP) | VAF 54/99 reads (55%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIRREL2 | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRTAP24-1 | c.248C>G p.T83S | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- LAMA1 | c.7626G>T p.V2542= | Splice Region (SNP) | VAF 9/49 reads (18%) | called by muse, mutect2, varscan2
- LINGO2 | c.307A>G p.N103D | Missense Mutation (SNP) | VAF 22/323 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.062); called by muse, mutect2
- LPAR4 | c.811T>A p.L271M | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- LRIG2 | c.2005G>A p.D669N | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC15 | c.1089G>T p.M363I | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- LRRC55 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.228); called by muse, mutect2
- LUM | c.487T>A p.F163I | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAGEB1 | c.359T>G p.L120R | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAGEB18 | c.605T>C p.I202T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MAP4K5 | c.1983A>G p.I661M | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MBD4 | c.1381A>G p.I461V | Missense Mutation (SNP) | VAF 66/240 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- MEFV | c.2329G>T p.G777C | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MPDZ | c.578del p.G193Dfs*26 | Frame Shift Del (DEL) | VAF 64/319 reads (20%) | called by mutect2, pindel, varscan2
- MUC16 | c.24343C>T p.P8115S | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- N4BP2L2 | c.1106G>C p.R369T | Missense Mutation (SNP) | VAF 67/193 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- NBAS | c.3470A>T p.H1157L | Missense Mutation (SNP) | VAF 34/260 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NEURL1 | c.513G>T p.W171C | Missense Mutation (SNP) | VAF 47/86 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NLRP3 | c.2977C>A p.Q993K | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- NLRP6 | c.2345G>A p.W782* | Nonsense Mutation (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2, varscan2
- NLRP8 | c.1988C>A p.T663N | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NOTCH1 | c.2916del p.A973Qfs*206 | Frame Shift Del (DEL) | VAF 30/113 reads (27%) | called by pindel, varscan2
- OAT | c.1318T>A p.*440Rext*2 | Nonstop Mutation (SNP) | VAF 131/233 reads (56%) | called by muse, mutect2, varscan2
- OBSCN | c.9065C>T p.A3022V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- OR10A4 | c.692C>G p.S231* | Nonsense Mutation (SNP) | VAF 30/115 reads (26%) | called by muse, mutect2, varscan2
- OR10G8 | c.754G>T p.G252C | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- OR2S2 | c.880C>G p.P294A | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- OR4K15 | c.854C>T p.P285L (on ENST00000305051; = p.P261L on NM_001005486.1) | Missense Mutation (SNP) | VAF 73/169 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR5T2 | c.902C>A p.P301Q | Missense Mutation (SNP) | VAF 48/252 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- OR5W2 | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- OR6V1 | c.172T>G p.Y58D | Missense Mutation (SNP) | VAF 92/377 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OSTF1 | c.634G>T p.D212Y | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- OTOGL | c.4262G>A p.C1421Y (on ENST00000547103; = p.C1412Y on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PADI4 | c.847G>A p.V283M | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- PAGE3 | c.297G>T p.E99D | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT tolerated (0.32); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- PCDH15 | c.4504C>A p.L1502I | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- PCDHGA1 | c.1241T>A p.L414H | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PDE6B | c.1596G>C p.K532N | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PIEZO2 | c.7634A>C p.K2545T | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.997); called by muse, mutect2
- PKHD1L1 | c.7244C>A p.T2415K | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- PRAME | c.1010G>T p.G337V | Missense Mutation (SNP) | VAF 112/269 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- RAB17 | c.53del p.R18Lfs*23 | Frame Shift Del (DEL) | VAF 15/92 reads (16%) | called by mutect2, varscan2
- RAB28 | c.649A>T p.M217L | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBFA | c.923T>G p.V308G | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RBM8A | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- RELN | c.6112C>A p.P2038T | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- RIMS1 | c.22del p.R8Afs*18 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | called by mutect2, pindel, varscan2
- RIMS1 | c.4484A>G p.N1495S | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- RIPK2 | c.1075G>T p.E359* | Nonsense Mutation (SNP) | VAF 48/268 reads (18%) | called by muse, mutect2, varscan2
- SEC16B | c.1220A>T p.N407I | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- SHOX2 | c.716A>G p.N239S (on ENST00000441443 / NM_006884.3; = p.N263S on NM_003030.4) | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- SIPA1 | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC14A2 | c.2363T>C p.M788T | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- SNAP91 | c.72A>C p.R24S | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SOGA3 | c.1759C>G p.L587V | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPHKAP | c.1500A>T p.L500F | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SPIDR | c.1399G>T p.D467Y | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SPRR2B | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- SRRM4 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- TACC2 | c.6721G>T p.E2241* (on ENST00000334433; = p.E319* on NM_006997.4) | Nonsense Mutation (SNP) | VAF 28/54 reads (52%) | called by muse, mutect2, varscan2
- TBX3 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TBX5 | c.665T>C p.I222T | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TCF21 | c.92T>A p.F31Y | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.062); called by muse, varscan2
- TMEM176B | c.406T>A p.F136I | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM260 | c.1271A>T p.K424M | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- TNPO3 | c.2419del p.V807* | Frame Shift Del (DEL) | VAF 25/141 reads (18%) | called by mutect2, pindel, varscan2
- TRIM27 | c.487del p.Q163Rfs*10 | Frame Shift Del (DEL) | VAF 26/240 reads (11%) | called by mutect2, varscan2
- TRPC1 | c.1478A>G p.H493R (on ENST00000476941 / NM_001251845.2; = p.H459R on NM_003304.4) | Missense Mutation (SNP) | VAF 54/207 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TSC2 | c.1663G>T p.A555S | Missense Mutation (SNP) | VAF 116/228 reads (51%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TTC21B | c.1804A>T p.T602S | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC29 | c.808A>T p.K270* | Nonsense Mutation (SNP) | VAF 6/11 reads (55%) | called by muse, mutect2, varscan2
- TTLL9 | c.166G>T p.D56Y | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TUBGCP5 | c.1267G>T p.V423F | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TXK | c.360del p.W120* | Frame Shift Del (DEL) | VAF 31/280 reads (11%) | called by mutect2, pindel, varscan2
- UBR2 | c.4502G>T p.G1501V | Missense Mutation (SNP) | VAF 64/182 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- UNC45B | c.589C>A p.L197M | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- VAMP7 | c.471G>T p.L157F | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VPS13C | c.6910A>G p.K2304E (on ENST00000644861 / NM_020821.3; = p.K2261E on NM_017684.5) | Missense Mutation (SNP) | VAF 79/167 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- WASHC5 | c.200G>T p.W67L | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- WASL | c.1442C>G p.A481G | Missense Mutation (SNP) | VAF 122/452 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, varscan2
- ZAN | c.1612G>T p.V538L | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- ZFC3H1 | c.2741G>C p.G914A | Missense Mutation (SNP) | VAF 67/177 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- ZFHX4 | c.13G>T p.D5Y | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZFHX4 | c.9613G>T p.E3205* | Nonsense Mutation (SNP) | VAF 22/88 reads (25%) | called by muse, mutect2, varscan2
- ZNF143 | c.860A>G p.H287R | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ZNF37A | c.98A>G p.Y33C | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF416 | c.742G>T p.G248W | Missense Mutation (SNP) | VAF 39/269 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ZNF462 | c.4730A>T p.Y1577F | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ZNF521 | c.3229A>T p.K1077* | Nonsense Mutation (SNP) | VAF 14/84 reads (17%) | called by muse, mutect2, varscan2
- ZNF521 | c.258G>T p.W86C | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABCA1 | c.111G>T p.L37= | Silent (SNP) | VAF 32/83 reads (39%) | called by muse, mutect2, varscan2
- ABCC5 | c.3471C>T p.F1157= | Silent (SNP) | VAF 46/605 reads (8%) | called by muse, mutect2
- ACER3 | c.111A>T p.T37= | Silent (SNP) | VAF 30/113 reads (27%) | called by muse, mutect2, varscan2
- ACMSD | c.423C>A p.V141= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV99299534; called by muse, mutect2, varscan2
- ADAMTS8 | c.2190G>T p.G730= | Silent (SNP) | VAF 19/126 reads (15%) | called by muse, mutect2, varscan2
- ADGRA2 | c.585C>T p.D195= | Silent (SNP) | VAF 28/134 reads (21%) | catalogued as COSV100177678; called by muse, mutect2, varscan2
- ADGRE1 | c.1452G>A p.V484= | Silent (SNP) | VAF 50/136 reads (37%) | called by muse, mutect2, varscan2
- AK5 | c.1567C>A p.R523= (on ENST00000354567 / NM_174858.3; = p.R497= on NM_012093.4) | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as rs763224649; called by muse, mutect2, varscan2
- ANKS1B | c.1230G>T p.P410= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV100245887; called by muse, mutect2, varscan2
- APLNR | c.510C>A p.T170= | Silent (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2, varscan2
- APOA5 | c.24C>G p.L8= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV99911447; called by muse, mutect2, varscan2
- CASP9 | c.615C>T p.G205= | Silent (SNP) | VAF 20/204 reads (10%) | catalogued as rs758088384, COSV100423860; called by muse, mutect2
- CDHR3 | c.1494C>T p.S498= | Silent (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2
- CEP170 | c.4209G>C p.R1403= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV100317292; called by muse, mutect2, varscan2
- CLIP4 | c.1137A>T p.V379= | Silent (SNP) | VAF 29/123 reads (24%) | called by muse, mutect2, varscan2
- COL6A6 | c.459C>A p.A153= | Silent (SNP) | VAF 26/115 reads (23%) | called by muse, mutect2, varscan2
- CUBN | c.5823G>A p.L1941= | Silent (SNP) | VAF 35/89 reads (39%) | called by muse, mutect2, varscan2
- CYP24A1 | c.579C>G p.L193= | Silent (SNP) | VAF 49/221 reads (22%) | catalogued as COSV53775129; called by muse, mutect2, varscan2
- DCHS1 | c.5583G>T p.S1861= | Silent (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- DNAH8 | c.4863T>C p.H1621= | Silent (SNP) | VAF 25/128 reads (20%) | catalogued as COSV100544205; called by muse, mutect2, varscan2
- DOT1L | c.1377G>T p.P459= | Silent (SNP) | VAF 80/188 reads (43%) | called by muse, mutect2, varscan2
- FAT1 | c.7722A>T p.G2574= | Silent (SNP) | VAF 18/48 reads (38%) | called by muse, mutect2, varscan2
- FGGY | c.1452C>G p.S484= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV58026973, COSV58046049; called by muse, mutect2, varscan2
- FOXD4L1 | c.735C>T p.V245= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as COSV99380655; called by muse, mutect2, varscan2
- GALNT3 | c.1860A>G p.P620= | Silent (SNP) | VAF 22/66 reads (33%) | called by muse, mutect2, varscan2
- GALNTL5 | c.819G>A p.R273= | Silent (SNP) | VAF 35/166 reads (21%) | called by muse, mutect2, varscan2
- GASK1B | c.1380G>A p.L460= | Silent (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
- GPI | c.1347C>A p.L449= | Silent (SNP) | VAF 13/60 reads (22%) | called by muse, mutect2, varscan2
- GRM8 | c.2103C>T p.S701= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as COSV100279331, COSV58836046; called by muse, mutect2, varscan2
- HECTD4 | c.11652C>T p.D3884= | Silent (SNP) | VAF 52/140 reads (37%) | catalogued as rs771512946, COSV66390505; called by muse, mutect2, varscan2
- HMCN1 | c.3834A>G p.R1278= | Silent (SNP) | VAF 14/119 reads (12%) | called by muse, mutect2, varscan2
- LCE1D | c.210C>T p.G70= | Silent (SNP) | VAF 41/92 reads (45%) | catalogued as COSV100405873; called by muse, mutect2, varscan2
- LHCGR | c.1725C>T p.I575= | Silent (SNP) | VAF 8/180 reads (4%) | catalogued as COSV54293295; called by muse, mutect2
- LINGO3 | c.834G>A p.S278= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as COSV101347241; called by muse, mutect2, varscan2
- LSG1 | c.1632G>A p.L544= | Silent (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- MAP1LC3C | c.192G>C p.L64= | Silent (SNP) | VAF 17/124 reads (14%) | called by muse, mutect2, varscan2
- MAP2 | c.3333A>G p.K1111= | Silent (SNP) | VAF 47/127 reads (37%) | called by muse, mutect2, varscan2
- MEPCE | c.768C>T p.L256= | Silent (SNP) | VAF 125/518 reads (24%) | catalogued as rs776556305; called by muse, mutect2, varscan2
- MIOS | c.798A>G p.Q266= | Silent (SNP) | VAF 34/123 reads (28%) | called by muse, mutect2, varscan2
- MOSPD2 | c.183A>C p.T61= | Silent (SNP) | VAF 85/131 reads (65%) | called by muse, mutect2, varscan2
- NACA | c.267A>G p.T89= | Silent (SNP) | VAF 125/510 reads (25%) | called by muse, mutect2, varscan2
- NECTIN4 | c.1218G>A p.T406= | Silent (SNP) | VAF 16/206 reads (8%) | catalogued as rs1453106973, COSV63512799, COSV63512816; called by muse, mutect2
- PODXL | c.258C>T p.S86= | Silent (SNP) | VAF 12/121 reads (10%) | called by muse, varscan2
- POTEF | c.2703C>A p.T901= | Silent (SNP) | VAF 38/74 reads (51%) | catalogued as COSV100665086; called by muse, mutect2, varscan2
- RSBN1L | c.1494A>G p.P498= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as rs201420980; called by muse, mutect2, varscan2
- SH3PXD2B | c.1527G>A p.E509= | Silent (SNP) | VAF 49/96 reads (51%) | catalogued as COSV61126289; called by muse, mutect2, varscan2
- SLC36A1 | c.105G>T p.P35= | Silent (SNP) | VAF 29/75 reads (39%) | called by muse, mutect2, varscan2
- SYCP2L | c.1530A>G p.Q510= | Silent (SNP) | VAF 20/80 reads (25%) | called by muse, mutect2, varscan2
- SYT14 | c.1077G>A p.V359= | Silent (SNP) | VAF 43/117 reads (37%) | catalogued as rs532632303; called by muse, mutect2, varscan2
- TAS1R3 | c.2376C>A p.A792= | Silent (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2, varscan2
- THBS2 | c.1269G>T p.R423= | Silent (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- TREM1 | c.474C>G p.T158= | Silent (SNP) | VAF 31/99 reads (31%) | called by muse, mutect2, varscan2
- TRPM6 | c.1017G>A p.L339= | Silent (SNP) | VAF 32/71 reads (45%) | catalogued as rs1431067303, COSV100667198; called by muse, mutect2, varscan2
- TYW3 | c.435G>A p.R145= | Silent (SNP) | VAF 37/110 reads (34%) | catalogued as COSV63802882; called by muse, mutect2, varscan2
- VPS13B | c.6075A>G p.P2025= | Silent (SNP) | VAF 25/98 reads (26%) | called by muse, mutect2, varscan2
- WIZ | c.2505C>T p.H835= (on ENST00000673675 / NM_001371589.1; = p.H98= on NM_021241.3) | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as rs752631156; called by muse, mutect2, varscan2
- ZNF804A | c.543C>A p.T181= | Silent (SNP) | VAF 37/104 reads (36%) | called by muse, mutect2, varscan2
- C21orf62 | c.*75C>A | 3'UTR (SNP) | VAF 10/63 reads (16%) | catalogued as COSV101212327; called by muse, mutect2, varscan2
- C7orf66 | n.226A>G | RNA (SNP) | VAF 39/166 reads (23%) | catalogued as rs1468575861; called by muse, mutect2, varscan2
- HNRNPU | c.634+38C>T | Intron (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- PRR14L | chr22:31676890 G>T | 3'Flank (SNP) | VAF 9/17 reads (53%) | called by muse, mutect2, varscan2
- RN7SL176P | chr12:100157707 G>A | 3'Flank (SNP) | VAF 6/44 reads (14%) | catalogued as rs371455895; called by muse, mutect2, varscan2
- SLITRK2 | chrX:145827710 A>G | 3'Flank (SNP) | VAF 15/31 reads (48%) | called by muse, mutect2, varscan2
